Surgical pathology report (de-identified scan), TCGA case TCGA-P7-A5NX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Translational Genomics Research Institute, specimen TCGA-P7-A5NX-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [Redacted]
Med. Rec. #: [Redacted]
DOB: [Redacted]
Gender: F
Physician(s): [Redacted]

Location: [Redacted]
Service: [Redacted]
Billing #: [Redacted]

Accession #: [Redacted]
Billing Type: [Redacted]
Taken: [Redacted]
Received: [Redacted]
Reported: [Redacted]

Specimen(s) Received

Left adrenal gland tumor

Pathologic Diagnosis

Adrenal gland, left, tumor, excision:
- Pheochromocytoma, see note.

Note: The lesion measures 2.7 cm in greatest dimension, and appears to be contained within the body of the adrenal gland (Evaluation is somewhat limited due to tissue fragmentation). The tumor is comprised of spindled and epithelioid cells arranged in a classic nested pattern. There is no nuclear atypia or necrosis present. Mitotic figures are sparse, (<1MF/50 HPFs), and there is no evidence of capsular or vascular space invasion. The tumor cells are immunoreactive for synaptophysin and chromogranin. Pertinent negatives include calretinin, inhibin, and Melan A. The morphologic and immunohistochemical features are consistent with the above diagnosis. A proliferation index by Ki-67 (Mib-1), has been ordered and the results will be reported as an addendum.

Primary Pathologist:
Electronically Signed Out by:

Clinical History

Left adrenal mass.

ILD-0-3
Pheochromocytoma 870013
Site Adrenal Gland NOS
074.9
JW 4/29/13

Gross Description

Received in formalin labeled "left adrenal gland tumor" is an adrenal gland with attached adipose tissue. The adrenal mass is disrupted or has been previously transected. With the adipose tissue trimmed away, the adrenal gland weighs 10 g and measures 5 x 3 x 2 cm.

The portions of the intact surface of the adrenal gland and mass are inked blue. Sectioning demonstrates the adrenal gland and mass are soft and friable. The mass is at least 2.7 cm in greatest dimension (the true greatest dimension is difficult to determine because the mass is disrupted or has been previously transected. The edges of the mass are ill-defined, and portions of the mass appear to be missing,

[page 2 of 2]
Surgical Pathology Report

presumed due to the friability. Including the edges of the ill-defined, friable area, the mass is possibly 3.1 cm in greatest dimension).

The mass is golden tan-yellow with diffuse areas of hemorrhage. The remainder of the adrenal gland is golden tan-yellow and grossly unremarkable. There are no additional lesions or suspicious areas identified.

Representative sections of the mass are submitted in cassettes 1 through 4. Representative sections of the normal adrenal gland are submitted in cassette 5.

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

A: 88307, 88342, 88342, 88342, 88342, 88342, 88342

If immunohistochemistry or in situ hybridization was used the following applies: This test was developed and its performance characteristic determined by . It has not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA does not require this test to go through premarket FDA review. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing. All special stains used have adequate controls.

Histology Discrepancy		✓
Prior Imaging History		✓
Qual/2. Multicentric Primary Notes		✓
Case is Circled	INITIALS	INITIALS

Source: NCI Genomic Data Commons file 99422944-0b0f-4d85-9004-e06e4e898e02 (TCGA-P7-A5NX.B4FD193B-5624-4AF0-81B6-93B2AFC1895B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).